Gene-level copy-number profile of tumor specimen TCGA-CN-6011-01A from TCGA case TCGA-CN-6011, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Gum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 57.5 years (21,016 days).
Specimen TCGA-CN-6011-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.3b2bdc72-16de-434b-81fc-96fbab45a490.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-6011-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/49edf737-d07b-4d74-a602-ee76cf1415e3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 676; copy number 2: 21,803; copy number 3: 30,571; copy number 4: 4,862; copy number 5: 615; copy number 6: 167; copy number 8: 699; copy number 9: 73; copy number 10: 3; copy number 12: 274; copy number 13: 2; copy number 19: 1; copy number 22: 57; copy number 27: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-6011-01A-11D-1682-01): tumor purity 0.68, ploidy 2.77, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,690,719, 3 genes: AC104164.2, MIR548BB, PPIAP70.
- chr4:91,108,023–91,112,790, 1 gene: AC004054.1.
- chr5:59,703,606–59,703,703, 1 gene: MIR582.
- chr9:21,966,929–21,995,301, 2 genes: CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,009,305, 2 genes: AL449423.1, CDKN2B.
- chr18:49,560,699–49,599,185, 1 gene: LIPG.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,110 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:198,493,242–199,476,935, 7 genes, copy number 8 (within-gene range 4–8): AC019330.1, AC020718.1, AC018717.1, RNU7-147P, SATB2, AC016746.1, SATB2-AS1.
- chr5:1,708,785–45,895,970, 647 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr7:91,311,368–91,515,427, 1 gene, copy number 10 (within-gene range 2–10): AC079760.2.
- chr7:91,380,778–91,643,512, 2 genes, copy number 10: AC079760.1, AC000058.1.
- chr9:14,475–22,029,594, 314 genes, copy number 8–12 (within-gene range 0–12) (broad region; genes not listed).
- chr9:21,994,139–22,128,103, 1 gene, copy number 12 (within-gene range 0–12): CDKN2B-AS1.
- chr9:22,046,758–22,455,740, 4 genes, copy number 12: AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr11:40,114,203–41,459,773, 1 gene, copy number 13 (within-gene range 5–27): LRRC4C.
- chr11:40,444,371–41,123,012, 2 genes, copy number 13–27: AC090720.1, RNU6-365P.
- chr11:67,119,263–68,284,879, 73 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr11:69,294,151–71,568,934, 58 genes, copy number 19–22: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2, KRTAP5-7, KRTAP5-8, KRTAP5-9, AP000867.5, KRTAP5-10, AP000867.1.

Autosomal genes at a single copy (total copy number 1): 671. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
